Somatic mutation profile of tumor specimen TCGA-EM-A22O-01A (aliquot TCGA-EM-A22O-01A-11D-A17V-08) from TCGA case TCGA-EM-A22O, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 76.0 years (27,758 days).
Specimen TCGA-EM-A22O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d21e0899-0880-4e83-9821-18582a35f900.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22O-10A (Blood Derived Normal), aliquot TCGA-EM-A22O-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16ea45e1-6952-4841-877e-6c2e0435f118

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- ATM | c.6394C>G p.L2132V | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as COSV53770735; called by muse, mutect2, varscan2
- ATXN2 | c.3616A>T p.T1206S (on ENST00000550104; = p.T1046S on NM_002973.4) | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV100374520, COSV57986264; called by muse, mutect2, varscan2
- ATXN7L2 | c.1801C>G p.L601V | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.352); catalogued as COSV60205884; called by muse, mutect2, varscan2
- CACNA2D4 | c.2498C>T p.T833M | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs532757608, COSV54566572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC39 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56492549; called by muse, mutect2, varscan2
- CDH19 | c.1432G>A p.V478I | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs758561860, COSV50974094; called by muse, mutect2, varscan2
- CDH23 | c.5120A>G p.Y1707C | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56486344; called by muse, mutect2
- CNKSR1 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV64164096; called by muse, mutect2
- CYP4F11 | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV56129250; called by muse, mutect2, varscan2
- DNAH3 | c.10034G>A p.R3345H | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756996425, COSV54547489; called by muse, mutect2, varscan2
- EPG5 | c.1958A>G p.Y653C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV56355323; called by muse, mutect2, varscan2
- FZD8 | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV101020210, COSV65968430; called by muse, mutect2, varscan2
- MAP1A | c.1673C>G p.P558R | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV55812047; called by muse, mutect2, varscan2
- NAP1L1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV53876303; called by muse, mutect2, varscan2
- NIPSNAP3A | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV66113144; called by muse, mutect2, varscan2
- NLRP8 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.665); catalogued as COSV52593035; called by muse, mutect2, varscan2
- SULF2 | c.2431A>T p.M811L | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as COSV59072774; called by muse, mutect2, varscan2
- TTC27 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV58656066; called by muse, mutect2, varscan2
- ZNF532 | c.1582A>T p.N528Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60175285; called by muse, mutect2
- ZNRF3 | c.1268A>G p.H423R (on ENST00000544604 / NM_001206998.2; = p.H323R on NM_032173.3) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV60437947; called by muse, mutect2, varscan2
- MIS18BP1 | c.1843del p.T615Qfs*12 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- CARS1 | c.1986G>A p.R662= | Silent (SNP) | VAF 50/305 reads (16%) | catalogued as rs775554829, COSV53460285; called by muse, mutect2, varscan2
- CDK15 | c.1131C>T p.S377= (on ENST00000652192 / NM_001366386.2; = p.S326= on NM_139158.2) | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as rs775231477, COSV53633466, COSV53637912; called by muse, mutect2
- DDX60L | c.855A>G p.L285= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs945541194, COSV52720828; called by muse, mutect2, varscan2
- PKP4 | c.2550C>T p.L850= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs779783061, COSV61580210; called by muse, mutect2, varscan2
- SDAD1 | c.1071T>C p.A357= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV62403710; called by muse, mutect2, varscan2
